Somatic mutation profile of tumor specimen 0DMKB6 from CCDI case PBCACU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 9.3 years (3,412 days).
Specimen 0DMKB6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c9fb793-8119-46df-963d-fb1c4fdaa12c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMKB1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f10b736-5eac-4b26-a349-95337a5bc42d

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 5, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.772A>G p.R258G | Missense Mutation (SNP) | VAF 221/620 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs863224846, CM156014, COSV55116294, COSV99717854; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- H3C2 | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 371/968 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV52517710, COSV52518111; called by muse, mutect2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 277/695 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BMPR2 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 146/480 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as CM1513949, COSV101001676; called by muse, mutect2, varscan2
- COL7A1 | c.8335G>A p.E2779K | Missense Mutation (SNP) | VAF 400/948 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs768818662, COSV56477316; called by muse, mutect2, varscan2
- DOCK4 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 259/699 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs769419101, COSV101455960; called by muse, mutect2, varscan2
- FPGS | c.1196G>T p.R399L | Missense Mutation (SNP) | VAF 158/506 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1302190697; called by muse, mutect2, varscan2
- INSYN2A | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 381/987 reads (39%) | SIFT tolerated (0.85); PolyPhen benign (0.009); catalogued as COSV54733483; called by muse, mutect2, varscan2
- MAGEB6 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 78/786 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs775192724, COSV66872018; called by muse, mutect2
- NDST2 | c.1138C>G p.R380G | Missense Mutation (SNP) | VAF 313/861 reads (36%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.546); catalogued as COSV100013765, COSV55212916; called by muse, mutect2, varscan2
- NLRC3 | c.1196C>T p.T399I | Missense Mutation (SNP) | VAF 57/434 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs1353112067; called by muse, mutect2, varscan2
- OR10H2 | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 448/1185 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.283); catalogued as rs751844869, COSV59945682; called by muse, mutect2, varscan2
- TINAGL1 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 115/178 reads (65%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs553436849; called by muse, mutect2, varscan2
- TMEM200A | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 352/997 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.153); catalogued as rs267600805, COSV51648937, COSV99758850; called by muse, mutect2, varscan2
- TRIML1 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 213/532 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.749); catalogued as rs369748946; called by muse, mutect2, varscan2
- APOA4 | c.688A>G p.T230A | Missense Mutation (SNP) | VAF 327/809 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- SACS | c.13561A>C p.N4521H | Missense Mutation (SNP) | VAF 396/996 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- TMF1 | c.1708C>A p.L570M | Missense Mutation (SNP) | VAF 15/505 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF717 | c.1418A>T p.H473L | Missense Mutation (SNP) | VAF 406/1217 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- AMDHD1 | c.286A>C p.R96= | Silent (SNP) | VAF 152/438 reads (35%) | called by muse, mutect2, varscan2
- CCDC57 | c.972C>T p.C324= | Silent (SNP) | VAF 220/621 reads (35%) | catalogued as rs1247073412; called by muse, varscan2
- H3C2 | c.81C>T p.R27= | Silent (SNP) | VAF 374/978 reads (38%) | catalogued as rs530192487, COSV52520301; called by muse, mutect2
- ITPR1 | c.633C>T p.S211= | Silent (SNP) | VAF 176/406 reads (43%) | catalogued as rs771314325, COSV100231810, COSV56978024; called by muse, mutect2, varscan2
- NOC3L | c.825C>A p.I275= | Silent (SNP) | VAF 195/530 reads (37%) | called by muse, mutect2, varscan2
- ENOSF1 | chr18:671365 C>G | 3'Flank (SNP) | VAF 119/324 reads (37%) | called by muse, mutect2, varscan2
